Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A13T, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A13T-01A (Primary Tumor).

[page 1 of 3]
Clinical Diagnosis & History:

History of thyroid nodule/ multinodular goiter. FNA- papillary carcinoma.

Specimens Submitted:

- 1: SP: Left para tracheal lymph nodes
- 2: SP: Thyroid; Total thyroidectomy

DIAGNOSIS:

1. SP: Lymph nodes, Left para tracheal lymph nodes; biopsy:
- Two benign lymph nodes, (0/2).

2. SP: Thyroid; Total thyroidectomy

Tumor Type:

Papillary carcinoma, classical type

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Other Tumor Features:

Psammoma bodies

Tumor Location:

Right lobe

Tumor Size:

Greatest diameter is 2.2 cm.

Tumor Encapsulation:

Completely surrounded

Capsular Invasion:

Foci of tumor-capsule invasion are noted

Blood Vessel Invasion:

Focal lymphovascular invasion is identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

ICD - 0 - 3

Carcinoma, Papillary, Thyroid

8260/3

hw

11/16/10

Site: Thyroid, Nos C73.9

[page 2 of 3]
Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

INPATIENT

Clinical Diagnosis & History:

History of thyroid nodule/ multinodular goiter. FNA- papillary carcinoma.

Specimens Submitted:

- 1: SP: Left para tracheal lymph nodes
- 2: SP: Thyroid; Total thyroidectomy

DIAGNOSIS:

- 1. SP: Lymph nodes, Left para tracheal lymph nodes; biopsy:
- Two benign lymph nodes, (0/2).

- 2. SP: Thyroid; Total thyroidectomy

Tumor Type:

Papillary carcinoma, classical type

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Other Tumor Features:

Psammoma bodies

Tumor Location:

Right lobe

Tumor Size:

Greatest diameter is 2.2 cm.

Tumor Encapsulation:

Completely surrounded

Capsular Invasion:

Foci of tumor-capsule invasion are noted

Blood Vessel Invasion:

Focal lymphovascular invasion is identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

[page 3 of 3]
Tumor Multicentricity:

Two microscopic foci noted - a 1.0mm focus on the right and a 2.4mm focus on the left

Non-Neoplastic Thyroid:

Exhibits chronic lymphocytic thyroiditis consistent with Hashimoto's thyroiditis

Parathyroid Glands:

Not identified

Lymph Nodes:

Five benign perithyroidal lymph nodes, (0/5)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1).The specimen is received fresh, labeled in" left paratracheal lymph node " and consists of a tan pink soft tissue measures 0.3 cm entirely submitted.

Summary of sections:

E- entire specimen

2).The specimen is received fresh, labeled in" total thyroidectomy " and consists of a thyroid weighing 32 grams. The right lobe measures 5.5x3x2 cm , the left lobe measures 5x3x2 cm and the isthmus measures 1x1x0.3 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a mass measuring 2.2 cm in greatest dimension in the right lobe. Sections through the remaining tissue reveal red tan and meaty parenchyma. Representative sections of the specimen are submitted for TPS, The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:

N - nodule

RL - right lobe

LL - left lobe

IS - isthmus

Summary of Sections:

Part 1: SP: Left para tracheal lymph nodes

Block	Sect. Site	PCs
1	e	1

Part 2: SP: Thyroid; Total thyroidectomy

Block	Sect. Site	PCs
2	is	2
8	ll	8
5	n	5
5	rl	5

Source: NCI Genomic Data Commons file 90a962ed-42df-4ec2-ab62-df68571abcc9 (TCGA-DJ-A13T.F5E0C7C9-0A8A-464A-A33F-00CA59772698.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).